Somatic mutation profile of tumor specimen MBCProject_4232_T1_WES (aliquot MBCProject_4232_T1_WES_1) from CMI case MBCProject_4232, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 64.8 years (23,683 days).
Specimen MBCProject_4232_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Omentum; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26346834-dfc1-418c-b675-79a5330e2265.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4232_SALIVA (Saliva), aliquot MBCProject_4232_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3076e109-4eca-4d6c-bf10-47b7b7619773

The open-access MAF lists 109 somatic variants for this specimen: 68 protein-altering or splice-affecting, 27 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 27, Intron 6, Nonsense Mutation 6, 5'UTR 4, RNA 3, Frame Shift Del 2, Splice Site 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51644535, COSV51645490, COSV99032088; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 72/385 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/158 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRG4 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs755144342; called by muse, mutect2, varscan2
- ASPRV1 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.06); catalogued as COSV100208392; called by mutect2, varscan2
- CCDC157 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs777925980; called by muse, mutect2, varscan2
- CNTNAP1 | c.3258C>G p.F1086L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV52854035; called by muse, mutect2
- CREB3L4 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374742421; called by muse, mutect2
- CYFIP2 | c.2549G>A p.R850Q (on ENST00000616178 / NM_001291722.2; = p.R825Q on NM_014376.4) | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.863); catalogued as rs58005665; called by muse, mutect2, varscan2
- DDX60 | c.2987G>A p.G996D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1398296788; called by muse, mutect2, varscan2
- ECM2 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | catalogued as COSV100755959; called by muse, mutect2
- GCK | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV67883940; called by muse, mutect2
- GINS1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs778068914; called by muse, mutect2, varscan2
- GPD1L | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391064289; called by muse, mutect2, varscan2
- GPR156 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs768056878, COSV59938182; called by muse, mutect2, varscan2
- IYD | c.192G>T p.W64C | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV57604643; called by muse, mutect2, varscan2
- MEIOB | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV58053898; called by muse, mutect2, varscan2
- MYH9 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53393275; called by muse, mutect2, varscan2
- NPC1L1 | c.3535A>G p.T1179A | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs895973476; called by muse, mutect2
- OR2Y1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs764456445, COSV57138133; called by muse, mutect2, varscan2
- OR6A2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs373299055; called by muse, mutect2, varscan2
- PRR36 | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated, low confidence (0.21); catalogued as COSV73401782; called by muse, mutect2, varscan2
- PUM2 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1173281455; called by muse, mutect2
- RB1 | c.34_42del p.T12_A14del | In Frame Del (DEL) | VAF 17/108 reads (16%) | catalogued as rs759465865; ClinVar: uncertain significance / likely benign; called by mutect2, pindel, varscan2
- RBAK | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs754366722; called by muse, mutect2
- RIMS2 | c.976G>A p.E326K (on ENST00000666250 / NM_001348490.2; = p.E134K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs562430054; called by muse, varscan2
- SFSWAP | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs767852404, COSV55522639; called by muse, mutect2, varscan2
- SHANK1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs539761857; called by muse, mutect2, varscan2
- SIN3B | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs761831913, COSV99932011; called by muse, mutect2, varscan2
- TIGD4 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs937712176; called by muse, mutect2, varscan2
- UBN2 | c.2662C>A p.H888N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs535696835; called by muse, mutect2, varscan2
- USP27X | c.1195G>T p.V399F | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV101455314; called by muse, mutect2
- WDR17 | c.3437A>G p.E1146G | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.427); catalogued as COSV54569767; called by muse, mutect2, varscan2
- ZNF560 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs766679978; called by muse, mutect2, varscan2
- ACOD1 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRA3 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2
- APOBEC4 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- BMS1 | c.2542T>A p.F848I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- BNIP2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- C1QTNF3 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CASP2 | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2
- CCDC168 | c.5347dup p.R1783Kfs*15 | Frame Shift Ins (INS) | VAF 22/103 reads (21%) | called by mutect2, pindel, varscan2
- CDH1 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- DAB2 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DBH | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ENTPD5 | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, varscan2
- FNIP1 | c.2709_2724del p.Q903Hfs*20 | Frame Shift Del (DEL) | VAF 43/308 reads (14%) | called by mutect2, pindel, varscan2
- GOLM1 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- HPSE | c.901A>G p.N301D | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KIAA1109 | c.2801G>C p.C934S | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- KNL1 | c.5662-1G>A p.X1888_splice (on ENST00000346991 / NM_170589.5; = p.X1862_splice on NM_144508.5) | Splice Site (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- MAGI3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOSPD1 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NAA15 | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NCF2 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- OR51G2 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PCDHGA4 | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB6 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PLEKHH3 | c.1005_1008del p.L336Pfs*3 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- RAX | c.105C>G p.I35M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELN | c.6362G>A p.W2121* | Nonsense Mutation (SNP) | VAF 43/158 reads (27%) | called by muse, mutect2, varscan2
- SACS | c.12457C>A p.L4153I | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SLC5A6 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, varscan2
- SPEF2 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRGAP3 | c.3040C>T p.H1014Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SUDS3 | c.889-1G>T p.X297_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | called by muse, varscan2
- TFAP2A | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZBTB16 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- AKAP17A | c.1137G>A p.L379= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1483827993; called by muse, mutect2
- ANTXR1 | c.219C>T p.F73= | Silent (SNP) | VAF 39/198 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.2292G>A p.E764= | Silent (SNP) | VAF 50/133 reads (38%) | called by muse, mutect2, varscan2
- ATP13A4 | c.1506G>T p.V502= | Silent (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- C18orf63 | c.1332A>G p.L444= | Silent (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- CDC42BPG | c.822G>A p.T274= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs56393929, COSV61346382; called by muse, mutect2, varscan2
- DCST1 | c.165C>T p.G55= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs1212448584, COSV55051611; called by muse, mutect2, varscan2
- FRMPD2 | c.3312C>G p.L1104= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV59720305; called by muse, mutect2, varscan2
- FSCB | c.618A>G p.E206= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs544184497; called by muse, mutect2, varscan2
- GIMAP4 | c.942G>A p.A314= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs764010824, COSV55431354; called by muse, mutect2
- GPC5 | c.46C>T p.L16= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- GRID1 | c.1671C>T p.L557= | Silent (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- HDAC1 | c.468C>T p.I156= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1198871575, COSV65191160; called by muse, mutect2, varscan2
- HELLS | c.639A>G p.Q213= | Silent (SNP) | VAF 10/183 reads (5%) | catalogued as rs1305608322; called by muse, mutect2
- HYDIN | c.11499C>A p.V3833= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- KIAA1210 | c.3658C>T p.L1220= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV68176504; called by muse, mutect2
- NLGN4X | c.831C>T p.I277= | Silent (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- NLRP14 | c.1503G>A p.G501= | Silent (SNP) | VAF 40/199 reads (20%) | catalogued as COSV55064570; called by muse, mutect2, varscan2
- OTOP3 | c.285G>A p.K95= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1443C>T p.D481= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV56535921; called by muse, mutect2, varscan2
- PLEK | c.711G>A p.L237= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- PRSS37 | c.66G>A p.Q22= | Silent (SNP) | VAF 35/194 reads (18%) | catalogued as COSV100633809; called by muse, mutect2, varscan2
- RAPGEF5 | c.1158C>T p.L386= (on ENST00000401957 / NM_001367602.2; = p.L689= on NM_012294.5) | Silent (SNP) | VAF 39/266 reads (15%) | catalogued as rs1562715358; called by muse, mutect2, varscan2
- SEZ6L2 | c.1893C>T p.F631= (on ENST00000308713 / NM_001114099.3; = p.F561= on NM_012410.4) | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, varscan2
- SLC6A7 | c.1902G>A p.S634= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1381656816; called by muse, varscan2
- TPTE | c.402C>A p.A134= (on ENST00000618007 / NM_199261.4; = p.A116= on NM_199259.4) | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- VPS18 | c.1878C>G p.L626= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- AKAP9 | c.5698-2994C>A | Intron (SNP) | VAF 100/377 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF35 | c.-1G>A | 5'UTR (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- ASTN1 | c.2482+76T>C | Intron (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- ISM2 | c.141+343G>A | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- KLF3-AS1 | n.702+843C>T | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- MIR518B | n.76C>T | RNA (SNP) | VAF 8/36 reads (22%) | catalogued as rs766083744; called by muse, mutect2
- MIR891A | n.16C>T | RNA (SNP) | VAF 6/44 reads (14%) | catalogued as rs781947164; called by muse, mutect2
- MKRN9P | n.445G>A | RNA (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
- NADK | c.264-1823C>T | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891278 G>A | 5'Flank (SNP) | VAF 39/155 reads (25%) | called by muse, mutect2, varscan2
- SH3RF3 | c.-134C>T | 5'UTR (SNP) | VAF 12/52 reads (23%) | catalogued as rs984597136; called by muse, mutect2, varscan2
- SLIT2 | c.1463-623G>A | Intron (SNP) | VAF 13/115 reads (11%) | catalogued as rs367747283; called by muse, mutect2, varscan2
- TMEM43 | c.-15G>A | 5'UTR (SNP) | VAF 37/179 reads (21%) | catalogued as rs1397752021; called by muse, mutect2, varscan2
- ZNF649 | c.-16C>T | 5'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as rs543216153, COSV100725439; called by muse, mutect2, varscan2
